Gene-level copy-number profile of tumor specimen TCGA-DF-A2KS-01A from TCGA case TCGA-DF-A2KS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3.
Specimen TCGA-DF-A2KS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.bb4cff70-b866-4f37-aa9e-745d32627ff0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DF-A2KS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/473c2f7d-70ac-4da0-abd0-8fa33408100a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 1,438; copy number 2: 18,459; copy number 3: 19,960; copy number 4: 14,876; copy number 5: 3,196; copy number 6: 1,503; copy number 8: 264; copy number 9: 70.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DF-A2KS-01A-11D-A18N-01): tumor purity 0.71, ploidy 3.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:50,560,087–55,146,645, 51 genes (within-gene range 0–1): MAPK4, AC012433.2, AC012433.1, MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.3, AC016383.2, AC016383.1, DCC, AC011155.1, VN1R76P, MIR4528, LINC01917, LINC01919, RPL29P32, AC090666.1, MBD2, SNORA37, AC093462.1, POLI, STARD6, C18orf54, SNRPGP2, CUPIN1P, AC090897.1, AC091135.1, AC091135.2, DYNAP, RAB27B, RPSAP57, AC007673.1, AC098848.1, CCDC68, MAP1LC3P, LINC01929, RNA5SP459.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:105,287,830–106,272,902, 10 genes, copy number 8: AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2.
- chr21:25,928,754–25,952,614, 2 genes, copy number 9: AP001442.1, RNU6-123P.

Autosomal genes at a single copy (total copy number 1): 1,438. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
